Somatic mutation profile of tumor specimen ALCH-B0CA-TTP1-A (aliquot ALCH-B0CA-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0CA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.7 years (20,726 days).
Specimen ALCH-B0CA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e281c7d2-280f-4676-b45e-f16fc9beb7f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CA-NB1-A (Blood Derived Normal), aliquot ALCH-B0CA-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5e1279e-72a4-4faa-a8f6-e342b4cad00f

The open-access MAF lists 224 somatic variants for this specimen: 151 protein-altering or splice-affecting, 53 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 53, Nonsense Mutation 11, RNA 7, Frame Shift Del 5, 5'Flank 4, Intron 3, Splice Region 3, 3'UTR 2, Splice Site 2, 5'UTR 2, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 100/386 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260583; called by muse, mutect2, varscan2
- STK11 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 98/363 reads (27%) | catalogued as rs121913324, CD132642, CM044071, COSV58819862; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 47/472 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.354); catalogued as rs1455850199, COSV99066152; called by muse, mutect2, varscan2
- AC097636.1 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs201908745; called by muse, mutect2, varscan2
- ANKRD18A | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57634906; called by muse, mutect2
- ATP11C | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558164; called by muse, mutect2
- BRAF | c.1861A>T p.N621Y (on ENST00000288602 / NM_001374244.1; = p.N581Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/397 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as CM060878, COSV56062673, COSV56077649, COSV56286119; called by muse, mutect2, varscan2
- CACNA1E | c.3568G>C p.D1190H | Missense Mutation (SNP) | VAF 20/495 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100702243, COSV62413249; called by muse, mutect2
- CCT8L2 | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63463005, COSV63463552; called by muse, mutect2, varscan2
- CFAP65 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 98/508 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745952417, COSV55390981; called by muse, mutect2, varscan2
- CFAP70 | c.2671C>G p.Q891E | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as COSV60286740; called by muse, mutect2
- CHTF18 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs758557963; called by muse, mutect2, varscan2
- CNNM2 | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 94/470 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1041170083; called by muse, mutect2, varscan2
- CORIN | c.1553G>A p.C518Y | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779393074, COSV99903503; called by muse, mutect2, varscan2
- CRNKL1 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 9/303 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV55622045, COSV99846631; called by muse, mutect2
- DOCK2 | c.4214-1G>C p.X1405_splice | Splice Site (SNP) | VAF 11/235 reads (5%) | catalogued as COSV99911511; called by muse, mutect2
- EFR3A | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 79/433 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54458139; called by muse, mutect2, varscan2
- EHD1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746917690; called by muse, mutect2
- ELAPOR1 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100884732; called by muse, mutect2
- FASTKD5 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418518; called by muse, mutect2
- FBXO5 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 17/445 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100000013; called by muse, mutect2
- FGF4 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 59/303 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs760825703, COSV51449457; called by muse, mutect2, varscan2
- FHOD3 | c.2537C>T p.P846L (on ENST00000359247 / NM_001281739.3; = p.P863L on NM_025135.5) | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs567922320; called by muse, mutect2, varscan2
- GSDMA | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 36/642 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373798049; called by muse, mutect2
- HSPG2 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 64/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778444704; called by muse, mutect2, varscan2
- LAMC1 | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV51179032; called by muse, mutect2
- LRP1B | c.5041G>C p.D1681H | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67217355, COSV67278039; called by muse, mutect2
- LYST | c.3624del p.Q1208Hfs*8 | Frame Shift Del (DEL) | VAF 40/343 reads (12%) | catalogued as COSV67707157; called by mutect2, varscan2
- MAGEL2 | c.3155G>A p.R1052Q | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs752626295, COSV58567539; called by muse, mutect2, varscan2
- MCM3AP | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV52438985; called by muse, mutect2
- NKAPL | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV59199700; called by muse, mutect2
- NKX2-6 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223447855; called by muse, mutect2, varscan2
- NUDT12 | c.937G>T p.V313F | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs376989086; called by muse, mutect2, varscan2
- PCDHA13 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV99166342; called by muse, mutect2
- PDE1C | c.158G>T p.R53I | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV58506678; called by muse, mutect2, varscan2
- PKDREJ | c.4284G>C p.M1428I | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV53553088; called by muse, mutect2
- PLD5 | c.1471G>C p.E491Q (on ENST00000442594; = p.E429Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/688 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV59146077; called by muse, mutect2
- PLEKHH1 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs765515437, COSV61286118; called by muse, mutect2, varscan2
- PPM1B | c.1197G>C p.M399I | Missense Mutation (SNP) | VAF 25/340 reads (7%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV56768241; called by muse, mutect2
- PPP2R5B | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 56/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs374703944; called by muse, varscan2
- PRORP | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51619388; called by muse, mutect2
- RBM33 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770844096; called by muse, mutect2, varscan2
- RHOBTB1 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 65/400 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769928956, COSV100558627; called by muse, mutect2, varscan2
- RNF213 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 29/660 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV60619000; called by muse, mutect2
- RPH3A | c.519G>C p.K173N (on ENST00000389385 / NM_001143854.2; = p.K169N on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66992848; called by muse, mutect2
- RTL3 | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV58185511; called by muse, varscan2
- SACS | c.11185C>A p.Q3729K | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as CM085679; called by muse, mutect2
- SFN | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as rs1232876831; called by muse, mutect2
- SLC19A3 | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 79/567 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1489682124; called by muse, mutect2, varscan2
- TLR4 | c.338C>A p.P113H (on ENST00000355622 / NM_138554.5; = p.P73H on NM_003266.4) | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100790682; called by muse, mutect2, varscan2
- TTN | c.40543G>A p.D13515N (on ENST00000591111; = p.D6091N on NM_003319.4) | Missense Mutation (SNP) | VAF 24/507 reads (5%) | PolyPhen benign (0.015); catalogued as rs1375058579, COSV60435312; called by muse, mutect2
- UGT1A7 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 30/600 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV60853241; called by muse, mutect2
- ZNF180 | c.1842C>G p.F614L | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99660119; called by muse, mutect2
- ABCA13 | c.13654C>G p.P4552A | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCB10 | c.1807A>G p.I603V | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT tolerated (0.78); PolyPhen benign (0.026); called by muse, mutect2
- ABCC3 | c.375T>G p.Y125* | Nonsense Mutation (SNP) | VAF 43/168 reads (26%) | called by muse, mutect2, varscan2
- AK9 | c.50A>C p.D17A | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4436C>A p.P1479H | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2
- ANKRD30B | c.1312T>G p.F438V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); called by mutect2, varscan2
- ARVCF | c.1557C>G p.F519L | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ATG9A | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ATP2B4 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- BAG4 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 24/648 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2
- BPTF | c.8562G>C p.M2854I | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.23); called by muse, mutect2
- CALHM6 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.069); called by muse, mutect2
- CCDC102A | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 64/338 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCN6 | c.574T>C p.Y192H | Missense Mutation (SNP) | VAF 108/545 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CCNL2 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- CDC42BPA | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- CEMP1 | c.516C>G p.H172Q | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); called by muse, mutect2
- CFAP97 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CHD6 | c.7903G>T p.A2635S | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CHD6 | c.7902G>T p.M2634I | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- COL6A5 | c.3337del p.V1113Lfs*15 | Frame Shift Del (DEL) | VAF 65/325 reads (20%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.2642G>T p.R881L | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.1477C>A p.L493I (on ENST00000520002; = p.L492I on NM_033225.6) | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DIABLO | c.466G>A p.E156K (on ENST00000443649 / NM_001278303.1; = p.E229K on NM_019887.6) | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2
- DMXL1 | c.3584C>G p.S1195C | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- DNAJC3 | c.1464C>G p.F488L | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- DST | c.21517-4G>T | Splice Region (SNP) | VAF 33/230 reads (14%) | called by muse, mutect2, varscan2
- DST | c.21517-5G>T | Splice Region (SNP) | VAF 31/227 reads (14%) | called by muse, mutect2, varscan2
- EFCAB5 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 30/208 reads (14%) | called by muse, mutect2, varscan2
- EFHC1 | c.407C>G p.P136R | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EMC1 | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ERICH1 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); called by muse, mutect2
- ERN1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2
- FASTKD5 | c.1650G>C p.E550D | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.061); called by muse, mutect2
- FAT2 | c.5446G>T p.D1816Y | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCGBP | c.1214A>T p.H405L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FSHR | c.2085C>A p.N695K | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2
- GABRA3 | c.1186T>A p.F396I | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GANAB | c.2759A>T p.D920V | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GOLGA3 | c.1239G>C p.E413D | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2
- GPR85 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.158); called by muse, mutect2
- IL20 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.306); called by muse, mutect2
- IRX4 | c.1546C>A p.P516T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KIAA0232 | c.1240C>G p.L414V | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- MAP3K20 | c.2010G>T p.R670S | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- MEIOC | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.146); called by muse, mutect2
- METTL18 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 15/144 reads (10%) | called by muse, varscan2
- MGA | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRTO4 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- MSRA | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- MUC12 | c.10357A>G p.T3453A (on ENST00000379442; = p.T3310A on NM_001164462.1) | Missense Mutation (SNP) | VAF 59/1942 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2
- MUC15 | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 12/364 reads (3%) | called by muse, mutect2
- MUC2 | c.2222C>A p.P741H | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- NAV1 | c.3266A>T p.E1089V | Missense Mutation (SNP) | VAF 22/483 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NEK8 | c.1736C>G p.S579W | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2
- NOC3L | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2
- NPM1 | c.582+8G>C | Splice Region (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- NUP153 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- NXF1 | c.1781G>A p.W594* | Nonsense Mutation (SNP) | VAF 31/263 reads (12%) | called by muse, mutect2, varscan2
- PCDHA7 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 110/802 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- PCDHB7 | c.607del p.E203Kfs*8 | Frame Shift Del (DEL) | VAF 35/189 reads (19%) | called by mutect2, pindel, varscan2
- PCDHGB5 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLXDC2 | c.980-1G>T p.X327_splice | Splice Site (SNP) | VAF 108/589 reads (18%) | called by muse, mutect2, varscan2
- PON1 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3905C>T p.S1302F | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAD9B | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 79/475 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RAPGEF4 | c.1744C>A p.L582I | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.158); called by muse, mutect2
- RASSF10 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- RNF32 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2
- RNF6 | c.1682G>C p.R561P | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUSC1 | c.2062C>G p.L688V (on ENST00000368352 / NM_001105203.2; = p.L219V on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SCGN | c.337A>T p.I113F | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SCN11A | c.3064G>C p.G1022R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, varscan2
- SGCD | c.126G>T p.M42I (on ENST00000435422 / NM_001128209.2; = p.M43I on NM_000337.5) | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- SGPP1 | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 22/431 reads (5%) | called by muse, mutect2
- SLC25A36 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC25A45 | c.32T>A p.I11N | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SOX6 | c.1273C>G p.L425V (on ENST00000528429 / NM_001145819.2; = p.L384V on NM_017508.3) | Missense Mutation (SNP) | VAF 14/459 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- SP8 | c.354C>A p.S118R (on ENST00000361443 / NM_198956.4; = p.S136R on NM_182700.6) | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- SYNE2 | c.4638C>G p.I1546M | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.215); called by muse, mutect2
- SZT2 | c.8716G>A p.E2906K (on ENST00000634258 / NM_001365999.1; = p.E2849K on NM_015284.4) | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.098); called by muse, mutect2
- TAAR5 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TAF4B | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 13/274 reads (5%) | called by muse, mutect2
- TCFL5 | c.1083_1084del p.E361Dfs*41 | Frame Shift Del (DEL) | VAF 67/554 reads (12%) | called by pindel, varscan2
- TDRD6 | c.4913G>T p.G1638V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX47 | c.695T>C p.M232T | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TEX51 | c.271G>A p.D91N (on ENST00000643416; = p.D73N on NM_001322244.2) | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2
- TMEM63C | c.1462C>G p.L488V | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2
- TMEM87A | c.359_368del p.T120Nfs*26 | Frame Shift Del (DEL) | VAF 17/134 reads (13%) | called by mutect2, pindel, varscan2
- TMEM94 | c.3219C>G p.I1073M | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2
- TNRC6B | c.3046G>T p.E1016* (on ENST00000454349 / NM_001162501.2; = p.E963* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 67/364 reads (18%) | called by muse, mutect2, varscan2
- UBD | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- ZDHHC8 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ZNF831 | c.4962G>T p.M1654I | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ZNF831 | c.4963A>T p.R1655* | Nonsense Mutation (SNP) | VAF 50/249 reads (20%) | called by muse, mutect2, varscan2
- ZPR1 | c.1197G>A p.M399I | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- ZSCAN2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); called by muse, mutect2
- ZYG11B | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ALS2CL | c.1371C>T p.F457= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- BLVRA | c.606A>C p.T202= | Silent (SNP) | VAF 100/549 reads (18%) | called by muse, mutect2, varscan2
- CCDC170 | c.96G>A p.R32= | Silent (SNP) | VAF 40/228 reads (18%) | catalogued as COSV53344531; called by muse, mutect2, varscan2
- CD34 | c.1035C>A p.T345= | Silent (SNP) | VAF 137/412 reads (33%) | called by muse, mutect2, varscan2
- CHFR | c.612C>G p.S204= | Silent (SNP) | VAF 44/248 reads (18%) | called by muse, mutect2
- CORIN | c.3054C>A p.G1018= | Silent (SNP) | VAF 48/294 reads (16%) | called by muse, mutect2, varscan2
- CRAMP1 | c.2643G>T p.R881= | Silent (SNP) | VAF 70/309 reads (23%) | called by muse, mutect2, varscan2
- CYP3A43 | c.1473A>G p.L491= (on ENST00000354829 / NM_057095.3; = p.L492= on NM_022820.5) | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as rs1412675918; called by muse, mutect2, varscan2
- DDR1 | c.2640A>G p.L880= (on ENST00000324771; = p.L843= on NM_001954.4) | Silent (SNP) | VAF 79/318 reads (25%) | catalogued as COSV61322628; called by muse, mutect2, varscan2
- ECE1 | c.1056C>G p.L352= | Silent (SNP) | VAF 24/402 reads (6%) | called by muse, mutect2
- ETFA | c.96C>G p.S32= | Silent (SNP) | VAF 118/619 reads (19%) | called by muse, varscan2
- FREM3 | c.4521G>A p.K1507= | Silent (SNP) | VAF 12/358 reads (3%) | called by muse, mutect2
- GK2 | c.1575T>C p.S525= | Silent (SNP) | VAF 46/282 reads (16%) | catalogued as rs748118317; called by muse, mutect2, varscan2
- HNF4G | c.102T>G p.G34= (on ENST00000354370 / NM_001330561.2; = p.G81= on NM_004133.5) | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV62966954; called by muse, mutect2, varscan2
- IGLV3-21 | c.21C>T p.L7= | Silent (SNP) | VAF 28/444 reads (6%) | called by muse, mutect2
- KIF2B | c.963C>A p.A321= | Silent (SNP) | VAF 89/565 reads (16%) | called by muse, mutect2, varscan2
- LARS2 | c.1461C>T p.F487= | Silent (SNP) | VAF 37/239 reads (15%) | called by muse, mutect2, varscan2
- MEFV | c.252G>A p.E84= | Silent (SNP) | VAF 44/462 reads (10%) | called by muse, mutect2
- MELK | c.1689G>T p.V563= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- METTL24 | c.342C>G p.L114= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as rs894323755; called by muse, mutect2
- MGAM2 | c.3741C>T p.L1247= | Silent (SNP) | VAF 28/506 reads (6%) | called by muse, mutect2
- MPI | c.594C>T p.F198= | Silent (SNP) | VAF 31/233 reads (13%) | catalogued as rs1399029075; called by muse, mutect2, varscan2
- NDUFAF6 | c.15G>A p.A5= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- NEB | c.7626C>G p.S2542= | Silent (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- NSD2 | c.2640C>T p.F880= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- PCDHA5 | c.510G>A p.R170= | Silent (SNP) | VAF 78/408 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1140T>A p.G380= | Silent (SNP) | VAF 58/327 reads (18%) | called by muse, mutect2, varscan2
- PGD | c.591G>A p.L197= | Silent (SNP) | VAF 34/496 reads (7%) | called by muse, mutect2
- PKDREJ | c.3024G>C p.L1008= | Silent (SNP) | VAF 16/355 reads (5%) | called by muse, mutect2
- PLCG1 | c.1881C>T p.L627= | Silent (SNP) | VAF 40/616 reads (6%) | catalogued as rs556073938, COSV54820817; called by muse, mutect2
- PRAME | c.1387C>T p.L463= | Silent (SNP) | VAF 24/456 reads (5%) | catalogued as rs200182963; called by muse, mutect2
- PZP | c.4401T>A p.A1467= | Silent (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- RANBP6 | c.2697C>T p.I899= | Silent (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- RC3H1 | c.3336C>T p.D1112= | Silent (SNP) | VAF 14/246 reads (6%) | catalogued as rs1292242468; called by muse, mutect2
- RIPOR2 | c.766C>T p.L256= | Silent (SNP) | VAF 34/443 reads (8%) | called by muse, mutect2
- RNF225 | c.819G>T p.T273= | Silent (SNP) | VAF 76/280 reads (27%) | called by muse, mutect2, varscan2
- RRNAD1 | c.1110C>G p.L370= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- SHH | c.702C>G p.L234= | Silent (SNP) | VAF 38/300 reads (13%) | catalogued as rs1324122120; called by muse, mutect2, varscan2
- SLC13A3 | c.1599C>A p.A533= | Silent (SNP) | VAF 42/218 reads (19%) | called by muse, varscan2
- SOWAHC | c.819C>G p.L273= | Silent (SNP) | VAF 22/237 reads (9%) | catalogued as rs772926970, COSV61779380; called by muse, mutect2
- SPTBN4 | c.5883C>T p.I1961= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as rs1382402782, COSV58953229; called by muse, mutect2
- SVEP1 | c.9252T>C p.N3084= | Silent (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- TEKT3 | c.804C>T p.D268= | Silent (SNP) | VAF 92/672 reads (14%) | catalogued as rs149266687; called by muse, mutect2, varscan2
- TLR4 | c.339C>A p.P113= (on ENST00000355622 / NM_138554.5; = p.P73= on NM_003266.4) | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as rs138924526; called by muse, mutect2, varscan2
- TMEM143 | c.1062C>T p.L354= | Silent (SNP) | VAF 10/151 reads (7%) | catalogued as rs1405501037; called by muse, mutect2
- TRIM22 | c.1338C>T p.F446= | Silent (SNP) | VAF 20/388 reads (5%) | called by muse, mutect2
- TTN | c.53295C>G p.L17765= (on ENST00000591111; = p.L10341= on NM_003319.4) | Silent (SNP) | VAF 25/448 reads (6%) | called by muse, mutect2
- TTN | c.31380A>G p.E10460= (on ENST00000591111; = p.E9533= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- TYMP | c.885C>T p.D295= | Silent (SNP) | VAF 26/243 reads (11%) | called by muse, mutect2, varscan2
- UNC13C | c.1203C>A p.G401= | Silent (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2, varscan2
- ZGRF1 | c.3441G>A p.L1147= | Silent (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- ZNF280A | c.354G>A p.K118= | Silent (SNP) | VAF 43/236 reads (18%) | called by muse, mutect2, varscan2
- ZNF729 | c.1062C>T p.G354= | Silent (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- ADGRE4P | n.1649C>T | RNA (SNP) | VAF 4/31 reads (13%) | catalogued as rs776284794; called by mutect2, varscan2
- AOC4P | n.269C>T | RNA (SNP) | VAF 41/237 reads (17%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916059 C>T | 5'Flank (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- ATP5MC2 | c.-31-1107G>A | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as rs1422462712; called by muse, mutect2, varscan2
- DCHS2 | n.5680C>A | RNA (SNP) | VAF 30/188 reads (16%) | catalogued as COSV100602867; called by muse, mutect2, varscan2
- EIF2AK3 | c.*37G>C | 3'UTR (SNP) | VAF 24/274 reads (9%) | catalogued as rs762715195; called by muse, mutect2
- FAM153CP | chr5:178055964 C>T | 3'Flank (SNP) | VAF 36/648 reads (6%) | called by muse, mutect2
- FAM53C | chr5:138338200 C>G | 5'Flank (SNP) | VAF 10/184 reads (5%) | catalogued as rs972983591; called by muse, mutect2
- FAT3 | c.13052-624G>A | Intron (SNP) | VAF 17/511 reads (3%) | called by muse, mutect2
- IL9R | c.-18G>A | 5'UTR (SNP) | VAF 49/329 reads (15%) | catalogued as rs771355346; called by muse, mutect2, varscan2
- MCCC2 | c.999+936A>C | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- NOC4L | c.-11T>C | 5'UTR (SNP) | VAF 13/57 reads (23%) | catalogued as rs1232534501; called by muse, mutect2, varscan2
- NPIPB10P | n.842G>A | RNA (SNP) | VAF 97/747 reads (13%) | catalogued as rs748012155; called by muse, varscan2
- OR3A4P | n.988T>C | RNA (SNP) | VAF 40/376 reads (11%) | called by muse, mutect2, varscan2
- OR56B3P | n.642C>A | RNA (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- POLR1B | chr2:112542190 A>G | 5'Flank (SNP) | VAF 33/204 reads (16%) | catalogued as rs956881910; called by muse, mutect2, varscan2
- SDHA | chr5:218279 G>T | 5'Flank (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- SDHAP3 | n.350G>C | RNA (SNP) | VAF 76/539 reads (14%) | called by muse, mutect2, varscan2
- TAFA2 | c.*48G>C | 3'UTR (SNP) | VAF 24/137 reads (18%) | catalogued as COSV69174685; called by muse, mutect2, varscan2
- Unknown | chr2:239762912 G>A | IGR (SNP) | VAF 22/536 reads (4%) | catalogued as rs901513300; called by muse, mutect2
